Somatic mutation profile of tumor specimen TCGA-HT-A615-01A (aliquot TCGA-HT-A615-01A-11D-A29Q-08) from TCGA case TCGA-HT-A615, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 38.0 years (13,892 days).
Specimen TCGA-HT-A615-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c92f5a4-414b-470f-8159-17e902525048.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A615-10A (Blood Derived Normal), aliquot TCGA-HT-A615-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61dbdcc0-52eb-4b16-96f3-f922c4651996

The open-access MAF lists 35 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 24, Silent 7, Splice Site 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARHGAP6 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs899041025, COSV57299169; called by muse, mutect2, varscan2
- ARMC9 | c.1189G>C p.A397P | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63023109; called by muse, mutect2, varscan2
- ATP8A1 | c.3466A>G p.T1156A | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs754168075, COSV52546109; called by muse, mutect2, varscan2
- CBLL2 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as rs200886998, COSV60370095; called by muse, mutect2, varscan2
- CD96 | c.1033C>T p.P345S (on ENST00000283285 / NM_198196.3; = p.P329S on NM_005816.5) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.056); catalogued as COSV51921507; called by muse, mutect2, varscan2
- CDC73 | c.550G>C p.A184P | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV66469982; called by muse, mutect2, varscan2
- CLIP2 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56285059; called by muse, mutect2, varscan2
- CSAG1 | c.114G>C p.R38S | Missense Mutation (SNP) | VAF 28/428 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.085); catalogued as COSV63400615, COSV63401087; called by muse, mutect2
- CUL4B | c.2212G>C p.E738Q | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as COSV60689273; called by muse, mutect2, varscan2
- DLG3 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as CM129383, COSV52083660; called by muse, mutect2, varscan2
- FAT4 | c.11380C>T p.R3794W | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs201859188; called by muse, mutect2, varscan2
- GPRC6A | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59955501; called by muse, mutect2, varscan2
- GRPR | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs994260006, COSV66670136; called by muse, mutect2, varscan2
- INTS3 | c.1082A>G p.N361S | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59681030; called by muse, mutect2
- KIF4B | c.2138G>A p.R713Q | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1179198998, COSV70530379, COSV70531050; called by muse, mutect2, varscan2
- MYO7A | c.1624A>G p.K542E | Missense Mutation (SNP) | VAF 98/263 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV68686781; called by muse, mutect2, varscan2
- OR4X1 | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV60723736; called by muse, mutect2, varscan2
- POSTN | c.218+1G>A p.X73_splice | Splice Site (SNP) | VAF 11/25 reads (44%) | catalogued as rs770657369, COSV65714338; called by muse, mutect2, varscan2
- SPTA1 | c.4708G>A p.A1570T | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.612); catalogued as rs778626016, COSV63748300; called by muse, mutect2, varscan2
- SSH1 | c.1903A>G p.I635V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV58459490; called by muse, mutect2, varscan2
- STK36 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs774397382, COSV55329975; called by muse, mutect2, varscan2
- TERT | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs776569822, COSV57210617; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM164 | c.781A>C p.T261P (on ENST00000372068 / NM_032227.4; = p.T112P on NM_017698.2) | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV55815146; called by muse, mutect2, varscan2
- URB2 | c.2590A>G p.I864V | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs768077441, COSV51028169; called by muse, mutect2, varscan2
- ZC4H2 | c.399-1G>T p.X133_splice | Splice Site (SNP) | VAF 24/76 reads (32%) | catalogued as COSV62005835; called by muse, mutect2, varscan2
- FUBP1 | c.92del p.F31Sfs*23 | Frame Shift Del (DEL) | VAF 67/150 reads (45%) | called by mutect2, pindel, varscan2
- MRM1 | c.158T>C p.F53S | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- API5 | c.462C>T p.F154= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV66634793; called by muse, mutect2, varscan2
- CBLC | c.417C>T p.F139= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs981330867, COSV54325521; called by muse, mutect2, varscan2
- CDYL2 | c.462C>T p.N154= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as rs140729164; called by muse, mutect2, varscan2
- NLRP5 | c.276C>T p.T92= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV66767006; called by muse, mutect2, varscan2
- PLIN4 | c.1083C>T p.T361= (on ENST00000301286; = p.T376= on NM_001367868.2) | Silent (SNP) | VAF 43/121 reads (36%) | catalogued as rs61730743; called by muse, mutect2, varscan2
- SLC52A2 | c.1200G>C p.G400= | Silent (SNP) | VAF 9/127 reads (7%) | catalogued as rs1018703655, COSV57353267; called by muse, mutect2
- SLIT2 | c.4041G>A p.Q1347= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV56591549; called by muse, mutect2
